Somatic mutation profile of tumor specimen ALCH-B478-TTP1-A (aliquot ALCH-B478-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B478, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 52.7 years (19,246 days).
Specimen ALCH-B478-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fe94430-0b36-40a4-9584-08c552a327ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B478-NB1-A (Blood Derived Normal), aliquot ALCH-B478-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ab1088a-cfd1-4e9a-8b71-d25ceb468886

The open-access MAF lists 46 somatic variants for this specimen: 33 protein-altering or splice-affecting, 8 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 8, Intron 3, RNA 1, Splice Region 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAND1 | c.920A>G p.Y307C | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV73338613; called by muse, mutect2
- CELSR2 | c.8624G>A p.R2875Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.222); catalogued as rs528804076, COSV99604958; called by muse, mutect2, varscan2
- EVI5 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV64830536; called by muse, mutect2
- FBN1 | c.8401G>A p.D2801N | Missense Mutation (SNP) | VAF 32/538 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs868087455, COSV57315304; called by muse, mutect2
- GALNT13 | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as rs747061747, COSV67226297; called by muse, mutect2
- KRR1 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 22/358 reads (6%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0); catalogued as rs980996973; called by muse, mutect2
- MFSD2B | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs577147505; called by muse, mutect2
- MYCBP2 | c.122G>A p.R41K (on ENST00000357337; = p.R79K on NM_015057.5) | Missense Mutation (SNP) | VAF 15/170 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs779283252, COSV100628831; called by muse, mutect2
- PSMD8 | c.494A>T p.E165V | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV104393761; called by muse, mutect2
- SMAD4 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 77/676 reads (11%) | catalogued as COSV61684971, COSV61693968; called by muse, mutect2, varscan2
- TECRL | c.578A>C p.H193P | Missense Mutation (SNP) | VAF 26/354 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs764234529; called by muse, mutect2
- DNAJC9 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- DSP | c.3089A>T p.K1030I | Missense Mutation (SNP) | VAF 25/280 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); called by muse, mutect2
- KTN1 | c.2297A>T p.N766I | Missense Mutation (SNP) | VAF 33/379 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); called by muse, mutect2
- MAP3K13 | c.830A>G p.H277R | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MRM1 | c.567C>G p.S189R | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MYO1F | c.2924G>A p.G975E | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.013); called by mutect2, varscan2
- NAT16 | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPIP5K2 | c.1522G>C p.V508L | Missense Mutation (SNP) | VAF 27/315 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.431); called by muse, mutect2
- PRKD3 | c.1785T>G p.H595Q | Missense Mutation (SNP) | VAF 40/367 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- PTPRN | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- QSOX2 | c.1610C>T p.P537L | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- RYR2 | c.11891A>G p.Q3964R | Missense Mutation (SNP) | VAF 28/256 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SAR1B | c.12A>G p.I4M | Missense Mutation (SNP) | VAF 38/440 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.059); called by muse, mutect2
- SCARA3 | c.1205C>G p.S402C | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- SYT17 | c.326T>G p.I109S | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.04); called by mutect2, varscan2
- TRPS1 | c.544G>T p.V182L (on ENST00000220888 / NM_001330599.2; = p.V195L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/422 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2
- UMPS | c.606G>C p.Q202H | Missense Mutation (SNP) | VAF 42/482 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, mutect2
- USP24 | c.4663G>A p.E1555K | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.034); called by muse, mutect2
- VEGFA | c.678-4T>G | Splice Region (SNP) | VAF 48/414 reads (12%) | called by muse, mutect2, varscan2
- ZDHHC5 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF479 | c.871C>T p.H291Y | Missense Mutation (SNP) | VAF 80/418 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZSCAN9 | c.953T>G p.V318G | Missense Mutation (SNP) | VAF 40/335 reads (12%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP2B3 | c.2742C>T p.Y914= | Silent (SNP) | VAF 40/136 reads (29%) | catalogued as rs1456923285; called by muse, mutect2, varscan2
- CPEB2 | c.2994C>T p.I998= | Silent (SNP) | VAF 44/702 reads (6%) | catalogued as rs1264894523; called by muse, mutect2
- ENPP3 | c.1728C>T p.F576= | Silent (SNP) | VAF 16/156 reads (10%) | called by muse, mutect2
- HMCN1 | c.7629A>G p.P2543= | Silent (SNP) | VAF 20/443 reads (5%) | called by muse, mutect2
- NLRP14 | c.1407C>T p.D469= | Silent (SNP) | VAF 82/832 reads (10%) | catalogued as rs186808803, COSV55065509; called by muse, mutect2
- RASSF7 | c.906G>A p.A302= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as rs372840376; called by muse, mutect2
- TRIM55 | c.879G>A p.K293= | Silent (SNP) | VAF 14/327 reads (4%) | catalogued as COSV52549623; called by muse, mutect2
- ZNF445 | c.390G>A p.L130= | Silent (SNP) | VAF 52/219 reads (24%) | called by muse, mutect2, varscan2
- GLRXP3 | n.191T>C | RNA (SNP) | VAF 49/590 reads (8%) | called by muse, mutect2
- KIF2C | c.70+13G>T | Intron (SNP) | VAF 14/187 reads (7%) | called by muse, mutect2
- PRMT5 | c.110+38G>T | Intron (SNP) | VAF 9/126 reads (7%) | catalogued as COSV53545864; called by muse, mutect2
- TAF10 | c.*1468C>T | 3'UTR (SNP) | VAF 42/582 reads (7%) | called by muse, mutect2
- ZNF813 | c.142+1531C>T | Intron (SNP) | VAF 18/172 reads (10%) | called by muse, mutect2, varscan2
